Somatic mutation profile of tumor specimen TCGA-EA-A410-01A (aliquot TCGA-EA-A410-01A-11D-A243-09) from TCGA case TCGA-EA-A410, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G2; Age at diagnosis: 51.3 years (18,720 days).
Specimen TCGA-EA-A410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee5fec78-41db-4156-b1a7-66fb7a491745.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A410-10A (Blood Derived Normal), aliquot TCGA-EA-A410-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbd22af8-607a-4617-94c0-0ef6dd2bcbea

The open-access MAF lists 1,762 somatic variants for this specimen: 1,331 protein-altering or splice-affecting, 393 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 932, Silent 393, Frame Shift Del 277, Nonsense Mutation 55, Frame Shift Ins 36, Intron 15, Splice Site 14, RNA 10, In Frame Del 9, Splice Region 6, 3'UTR 5, 5'UTR 4.

Variants (750 of 1,762; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA1 | c.85dup p.Q29Pfs*30 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | catalogued as rs753348565; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ARID1B | c.4831C>T p.R1611* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs1554236040, COSV51670259; ClinVar: pathogenic; called by muse, mutect2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ATP13A2 | c.2629G>A p.G877R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144701072, CM106850; ClinVar: pathogenic; called by muse, mutect2
- BRIP1 | c.1315C>T p.R439* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | catalogued as rs587780226, COSV52002119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB1 | c.2544del p.L849Cfs*15 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs760430056; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.8440C>T p.R2814* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as rs143457874, CM960418; ClinVar: pathogenic; called by muse, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912475, COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EOGT | c.1130G>A p.R377Q (on ENST00000383701 / NM_001278689.2; = p.R293Q on NM_173654.3) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776995, CM132505, COSV55153518; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 22/85 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 28/50 reads (56%) | catalogued as rs1057520291, CM093342, CM971451, COSV57458707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IFT140 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs431905521, CM123480, COSV68486776; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KCNQ2 | c.1229del p.P410Rfs*30 (on ENST00000359125 / NM_172107.4; = p.P400Rfs*12 on NM_004518.6) | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs886041339, CD094786; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- MAN2B1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746808159, CM124081, COSV55473782; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52414939; called by muse, mutect2, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- MMAA | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs150376474, COSV55582009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MTHFR | c.1267dup p.E423Gfs*6 | Frame Shift Ins (INS) | VAF 15/55 reads (27%) | catalogued as rs1557761665; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- PBX1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1553249136, COSV63344026; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 29/52 reads (56%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- SACS | c.6172dup p.S2058Ffs*2 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs1214399996; ClinVar: pathogenic; called by mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SERPINF2 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.409); catalogued as rs121965062, CM993195, COSV100131978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906850, CM110722, COSV59286247; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV100229020; called by muse, mutect2, varscan2
- AAMDC | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs1299909879, COSV100489988; called by muse, mutect2
- ABCA12 | c.5399C>T p.T1800M (on ENST00000272895 / NM_173076.3; = p.T1482M on NM_015657.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs541331115, COSV55955972; called by muse, mutect2, varscan2
- ABCA3 | c.2809G>A p.V937I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.013); catalogued as rs376036997; called by mutect2, varscan2
- ABCA9 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs1372122909, COSV60619911; called by muse, mutect2, varscan2
- ABCC4 | c.1129T>C p.S377P | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100972543; called by muse, mutect2, varscan2
- ABCC5 | c.2836del p.R946Gfs*15 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV99657198; called by mutect2, pindel, varscan2
- ABCC8 | c.3767C>T p.A1256V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV56856579; called by muse, mutect2
- ABHD17A | c.809G>A p.C270Y (on ENST00000292577 / NM_001130111.2; = p.C321Y on NM_031213.4) | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1249145658, COSV99171294; called by muse, mutect2, varscan2
- ABI1 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100697906; called by muse, mutect2, varscan2
- ABI3BP | c.2891C>T p.T964I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99427039; called by muse, mutect2, varscan2
- AC092143.1 | c.1463del p.G488Afs*24 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | catalogued as rs752133648; called by mutect2, pindel, varscan2
- ACACB | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746301361, COSV100622108; called by muse, mutect2, varscan2
- ACACB | c.6256C>T p.R2086* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as rs1399317882, COSV100622985; called by muse, mutect2, varscan2
- ACAD10 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100564241; called by muse, mutect2, varscan2
- ACE | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as rs369022610; called by muse, varscan2
- ACLY | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as rs387907386, COSV100709725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSBG1 | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV51910864; called by muse, mutect2, varscan2
- ACSM1 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369221835; called by muse, mutect2, varscan2
- ADAM18 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV55844898; called by muse, mutect2, varscan2
- ADAM19 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99977438; called by muse, mutect2, varscan2
- ADAM32 | c.338del p.T113Sfs*5 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as COSV65947563, COSV65954225; called by mutect2, pindel, varscan2
- ADAMTS17 | c.503A>G p.N168S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99170758; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2381T>C p.L794P | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.834); catalogued as COSV101001931; called by muse, mutect2, varscan2
- ADCK1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as rs199682998; called by muse, mutect2, varscan2
- ADCK5 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1222242540, COSV100450487; called by muse, mutect2, varscan2
- ADGRA1 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV66927644; called by muse, mutect2, varscan2
- ADGRB1 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60102657; called by muse, mutect2, varscan2
- ADGRF4 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.026); catalogued as COSV99348467; called by muse, mutect2, varscan2
- ADRB1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100992285; called by muse, mutect2, varscan2
- AFTPH | c.2699C>T p.A900V (on ENST00000238855 / NM_203437.3; = p.A873V on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53221206; called by muse, mutect2, varscan2
- AGAP4 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782598354, COSV101432668; called by muse, mutect2, varscan2
- AGRN | c.6097G>A p.A2033T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374026237; called by muse, mutect2, varscan2
- AGTRAP | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs146377549; called by muse, mutect2, varscan2
- AHCTF1 | c.4517C>A p.P1506H (on ENST00000366508; = p.P1480H on NM_015446.5) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100403821; called by muse, mutect2, varscan2
- AKAP9 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as rs199631609, COSV100662482, COSV62358459; called by muse, mutect2
- ALAS1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140582251, COSV100050354; called by muse, mutect2, varscan2
- ALDH2 | c.127A>G p.N43D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99923008; called by muse, mutect2, varscan2
- ALDH3B2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as rs111503561; called by muse, mutect2, varscan2
- ALDH4A1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99311974; called by muse, mutect2, varscan2
- ALG13 | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs972892187, COSV52638954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.792); catalogued as COSV100980080; called by muse, mutect2, varscan2
- ALOXE3 | c.1005del p.T336Pfs*4 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs1243712649; called by mutect2, pindel, varscan2
- ALS2CL | c.2075T>G p.L692R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760740178, COSV100015084; called by muse, mutect2, varscan2
- ALX3 | c.313del p.Q105Sfs*88 | Frame Shift Del (DEL) | VAF 23/53 reads (43%) | catalogued as rs759127084; called by mutect2, pindel, varscan2
- ALX4 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750798110, COSV100241111; called by muse, mutect2, varscan2
- AMER1 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs370645786, COSV57661542; called by muse, mutect2, varscan2
- AMER3 | c.585del p.R196Gfs*70 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as COSV58470642; called by mutect2, pindel, varscan2
- AMY1C | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs1225783628, COSV100915210; called by muse, mutect2, varscan2
- ANK1 | c.3235G>A p.E1079K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs368279119; called by muse, mutect2, varscan2
- ANKRD17 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1560584488, COSV100429317, COSV58220458; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD27 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1441887281, COSV60128555; called by muse, mutect2, varscan2
- ANO7 | c.611C>T p.A204V (on ENST00000274979; = p.A150V on NM_001370694.2) | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.255); catalogued as COSV51468070; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs759218332; called by mutect2, varscan2
- ANXA6 | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199949353, COSV100636950; called by muse, mutect2, varscan2
- AP5S1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs369900734; called by muse, mutect2, varscan2
- APBB1 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs766162217, COSV100194094; called by muse, mutect2, varscan2
- APOBEC3C | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.353); catalogued as rs756657821, COSV63865189; called by muse, mutect2, varscan2
- APOBEC3G | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101349083; called by muse, mutect2, varscan2
- AQR | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs780179363, COSV99333261; called by muse, mutect2, varscan2
- AR | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM983651, COSV101018445; called by muse, mutect2, varscan2
- ARAP2 | c.3380A>G p.D1127G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.31); catalogued as rs1440411941, COSV100394735; called by muse, mutect2, varscan2
- ARAP3 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs534103187, COSV99499784; called by muse, mutect2, varscan2
- ARFGAP2 | c.869A>C p.K290T | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV100125563; called by muse, mutect2
- ARGFX | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs752404821, COSV57682040; called by muse, mutect2
- ARHGAP32 | c.4742G>A p.R1581Q (on ENST00000310343 / NM_001378025.1; = p.R1232Q on NM_014715.4) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs765797475, COSV100089551, COSV59855102; called by muse, mutect2, varscan2
- ARHGAP32 | c.2827G>A p.V943I (on ENST00000310343 / NM_001378025.1; = p.V594I on NM_014715.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1028817449, COSV59852479; called by muse, mutect2, varscan2
- ARHGAP4 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100604074; called by muse, mutect2, varscan2
- ARHGAP5 | c.3898G>A p.G1300R (on ENST00000345122 / NM_001030055.2; = p.G1299R on NM_001173.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565402, COSV100565446, COSV61539072; called by muse, mutect2, varscan2
- ARHGEF17 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1047609049, COSV99735760; called by muse, mutect2, varscan2
- ARHGEF2 | c.1411C>T p.R471C (on ENST00000361247 / NM_001162383.2; = p.R443C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58106417; called by muse, mutect2, varscan2
- ARHGEF9 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.691); catalogued as COSV99491900; called by muse, mutect2, varscan2
- ARID1A | c.4348G>A p.G1450S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.397); catalogued as rs1330309030, COSV61372867; called by muse, mutect2, varscan2
- ARMC2 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs779864015, COSV100933579; called by muse, mutect2, varscan2
- ARMC5 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs539440145, COSV51657250; called by muse, mutect2, varscan2
- ARMC9 | c.7del p.D3? | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as COSV63019195, COSV63020816; called by mutect2, pindel, varscan2
- ARMCX2 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV100168178; called by muse, mutect2, varscan2
- ARSB | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs529444755, COSV53719930; called by muse, mutect2, varscan2
- ARSD | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as rs759669373, COSV99472176; called by muse, mutect2, varscan2
- ARVCF | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1480376529, COSV54267868; called by muse, mutect2
- ASMTL | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV101187784; called by muse, mutect2, varscan2
- ASTN2 | c.1840G>A p.A614T (on ENST00000313400 / NM_001365069.1; = p.A563T on NM_014010.5) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100528097; called by muse, mutect2, varscan2
- ATAD2 | c.1691G>A p.S564N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.557); catalogued as COSV99784786; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG4A | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619738; called by muse, mutect2, varscan2
- ATN1 | c.2731G>C p.V911L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.219); catalogued as COSV100755809; called by muse, mutect2, varscan2
- ATP13A1 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs769521754, COSV99179316; called by muse, mutect2, varscan2
- ATP1A2 | c.2315C>A p.S772Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767877; called by muse, mutect2, varscan2
- ATP6AP1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs782516905, COSV62340856; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATXN7L2 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs915397381, COSV60204156; called by muse, mutect2, varscan2
- AZI2 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99843634; called by muse, mutect2, varscan2
- B3GAT3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs562657438, COSV99605954; called by muse, mutect2, varscan2
- BAHCC1 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.743); catalogued as COSV100311713; called by muse, mutect2, varscan2
- BAZ1A | c.3586C>T p.R1196* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100701161; called by muse, mutect2, varscan2
- BAZ2A | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 44/95 reads (46%) | catalogued as COSV51644587; called by muse, mutect2, varscan2
- BCOR | c.3626G>A p.R1209H (on ENST00000378444 / NM_001123385.2; = p.R1175H on NM_017745.6) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1422527923, COSV100653405; called by muse, mutect2, varscan2
- BCS1L | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753443327, COSV99829038; called by muse, mutect2, varscan2
- BDKRB1 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs780064132, COSV99387896; called by muse, mutect2, varscan2
- BEND7 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs534620750, COSV100346581; called by muse, mutect2, varscan2
- BFSP2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.866); catalogued as COSV100183784; called by muse, mutect2, varscan2
- BICDL1 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1299940876, COSV99985852; called by muse, mutect2, varscan2
- BMP1 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs752066503, COSV60479579; called by muse, mutect2, varscan2
- BMP1 | c.2431C>T p.R811* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as rs898240891, COSV60531680; called by muse, mutect2, varscan2
- BOC | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs541680773, COSV56346647; called by muse, mutect2, varscan2
- BOD1L1 | c.5717G>A p.S1906N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99239497; called by muse, mutect2, varscan2
- BPIFB3 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs149644176; called by muse, mutect2, varscan2
- BRCA1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80357138, COSV100524305; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- BRF2 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99604968; called by muse, mutect2, varscan2
- BRPF3 | c.2561del p.P854Rfs*6 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs1413008697, COSV60208966; called by pindel, varscan2
- BRWD1 | c.6263A>G p.E2088G | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.172); catalogued as COSV100313529; called by muse, mutect2, varscan2
- BSN | c.7513del p.T2506Hfs*63 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as rs754418611; called by mutect2, pindel, varscan2
- BTBD17 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.174); catalogued as rs538575138, COSV64729915; called by muse, mutect2, varscan2
- BTBD9 | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1345836943, COSV58424020; called by muse, mutect2, varscan2
- BTN3A1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs754276670, COSV50025558; called by muse, mutect2, varscan2
- C12orf4 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs752707533, COSV99712763; called by muse, mutect2, varscan2
- C14orf28 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs749310294, COSV57333841; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C16orf46 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs368711170; called by muse, mutect2, varscan2
- C5AR1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100754025; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | catalogued as rs747591930; called by mutect2, varscan2
- C9orf116 | c.284G>A p.R95Q (on ENST00000429260 / NM_001048265.2; = p.G80R on NM_144654.3) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs756199997, COSV65646473; called by muse, mutect2, varscan2
- CA5A | c.621C>T p.D207= | Splice Region (SNP) | VAF 42/90 reads (47%) | catalogued as rs780125549, COSV59242387; called by muse, mutect2, varscan2
- CACNA1I | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770899366, COSV60814489; called by muse, mutect2, varscan2
- CACNA1I | c.4998G>A p.M1666I | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs1250679776, COSV100360485; called by muse, mutect2, varscan2
- CACNG6 | c.577C>T p.R193W (on ENST00000252729 / NM_145814.1; = p.R122W on NM_031897.2) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99403466; called by muse, mutect2, varscan2
- CACTIN | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99698588; called by muse, mutect2, varscan2
- CAMKK1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367817211; called by muse, mutect2, varscan2
- CAMTA2 | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs765389294, COSV61835926; called by muse, mutect2, varscan2
- CAP1 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 46/121 reads (38%) | catalogued as rs767873454, COSV61223108; called by muse, mutect2, varscan2
- CAPG | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs566538644, COSV55707124; called by muse, mutect2, varscan2
- CAPN13 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201284844; called by muse, mutect2, varscan2
- CARD10 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1346492547, COSV99324722; called by muse, mutect2, varscan2
- CARMIL1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs555687744, COSV61513796; called by muse, mutect2, varscan2
- CARNS1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs776913935, COSV57049877; called by muse, mutect2, varscan2
- CASKIN2 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1441788754, COSV58597420; called by muse, mutect2, varscan2
- CASP5 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99507660; called by muse, varscan2
- CBLL1 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV56028609; called by muse, mutect2, varscan2
- CCDC127 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99723012; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 76/105 reads (72%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC181 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as rs140518076; called by muse, mutect2, varscan2
- CCDC183 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1052477300, COSV100273402; called by muse, mutect2, varscan2
- CCDC47 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99854159; called by mutect2, varscan2
- CCDC74A | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as rs1307989518, COSV54608973; called by mutect2, varscan2
- CCDC85A | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV68155638; called by muse, mutect2, varscan2
- CCDC86 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV57124424, COSV99920158; called by muse, mutect2, varscan2
- CCDC88A | c.3505C>T p.R1169C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs1176588295, COSV99710534; called by muse, mutect2, varscan2
- CCL17 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs756502125, COSV54665217; called by muse, mutect2, varscan2
- CCNYL1 | c.970-1G>T p.X324_splice (on ENST00000295414 / NM_001330218.2; = p.X254_splice on NM_152523.2) | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99775912; called by muse, mutect2
- CCR7 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.692); catalogued as rs775899752, COSV55850253; called by muse, mutect2, varscan2
- CCZ1B | c.554A>G p.D185G | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV100367880; called by muse, mutect2, varscan2
- CD1E | c.106T>A p.S36T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100937012, COSV63771984; called by muse, mutect2
- CD320 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760524953, COSV100035825; called by muse, mutect2, varscan2
- CDC42BPB | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs144313805, COSV100775468; called by muse, mutect2, varscan2
- CDH19 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV100051668; called by muse, mutect2, varscan2
- CDH23 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs746961144, COSV54930019; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH24 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1231137903, COSV99399740; called by muse, varscan2
- CDH5 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs373056526; called by muse, mutect2, varscan2
- CDH8 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV54858989; called by muse, mutect2, varscan2
- CDK5RAP1 | c.206T>A p.L69* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs749659479, COSV59428661; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1309C>A p.R437S | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV100575508; called by muse, mutect2, varscan2
- CDKN1A | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1236971182, COSV55188980; called by muse, mutect2, varscan2
- CDYL2 | c.590A>G p.H197R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.045); catalogued as COSV101629578; called by muse, mutect2, varscan2
- CEACAM18 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV67283458; called by muse, mutect2, varscan2
- CEMIP2 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV100987402; called by muse, mutect2, varscan2
- CENPI | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs928336044, COSV54505958, COSV54506416, COSV54506899; called by muse, varscan2
- CEP112 | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs755140327, COSV101210780; called by muse, mutect2, varscan2
- CEP120 | c.2213del p.K738Rfs*29 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV100071584; called by mutect2, varscan2
- CEP162 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138324166, COSV57617396; called by muse, mutect2, varscan2
- CEP164 | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs377437628; called by muse, varscan2
- CEP95 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs374766116; called by muse, mutect2, varscan2
- CERKL | c.1223G>A p.G408E (on ENST00000339098 / NM_001030311.2; = p.G382E on NM_201548.5) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs776211842, COSV59211628; called by muse, mutect2, varscan2
- CFAP251 | c.1822G>C p.A608P | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV56609441, COSV99996163; called by muse, mutect2, varscan2
- CFAP46 | c.7214del p.P2405Lfs*5 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs1344439240; called by mutect2, pindel, varscan2
- CFAP46 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1384862715, COSV100886560; called by muse, mutect2, varscan2
- CFHR5 | c.1064T>A p.I355K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.834); catalogued as COSV99888915; called by muse, mutect2, varscan2
- CGGBP1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as COSV100531925; called by muse, mutect2, varscan2
- CHD3 | c.5275C>T p.R1759W (on ENST00000330494 / NM_001005273.3; = p.R1725W on NM_005852.4) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394994913, CM124584, COSV100177206; called by muse, mutect2, varscan2
- CHD4 | c.218del p.K73Rfs*129 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs1322050057; called by mutect2, pindel, varscan2
- CHD5 | c.4237G>A p.A1413T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99313798; called by muse, mutect2, varscan2
- CHD8 | c.6167G>A p.R2056Q (on ENST00000646647 / NM_001170629.2; = p.R1777Q on NM_020920.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs572070685, COSV63037144; called by muse, mutect2, varscan2
- CHI3L2 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.505); catalogued as COSV100869295; called by muse, mutect2, varscan2
- CHRD | c.2098C>T p.R700* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52606803, COSV52611271; called by muse, mutect2, varscan2
- CHRNA2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); catalogued as rs1299700179, COSV53556352, COSV53556461; called by muse, mutect2, varscan2
- CHST13 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as rs779854156, COSV100081119; called by muse, mutect2, varscan2
- CHST6 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs2550908; called by muse, mutect2, varscan2
- CKAP2L | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs536752121, COSV100198616; called by muse, mutect2, varscan2
- CKAP5 | c.583A>G p.I195V | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs770331121, COSV100370863; called by muse, mutect2, varscan2
- CLCN5 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs151340628, CM970316, COSV56582155; called by muse, mutect2, varscan2
- CLDN11 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs755485527, COSV50355418; called by muse, mutect2, varscan2
- CLDN23 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs890331017, COSV101093121; called by muse, mutect2, varscan2
- CLDN6 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100172211; called by muse, mutect2, varscan2
- CLEC18B | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); catalogued as rs779045021, COSV100375973; called by muse, mutect2, varscan2
- CLIC3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65406942; called by muse, mutect2, varscan2
- CLMN | c.2945T>A p.L982H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100112458; called by muse, mutect2, varscan2
- CLTB | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs570423413, COSV60044401; called by muse, mutect2, varscan2
- CNNM1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as rs1010898288, COSV63203259; called by muse, mutect2
- CNOT3 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs760484096, COSV99651928; called by muse, mutect2, varscan2
- CNTN3 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV99724684; called by muse, mutect2, varscan2
- CNTN4 | c.2075G>T p.R692L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as COSV100639315, COSV61868614; called by muse, mutect2, varscan2
- CNTNAP1 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029584700, COSV99226513; called by muse, mutect2, varscan2
- CNTRL | c.4646A>G p.K1549R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.188); catalogued as COSV99442604; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as rs374805044; called by mutect2, varscan2
- COG5 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1424122009, COSV51762293, COSV99772692; called by mutect2, varscan2
- COL12A1 | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs374544349, COSV59390123; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.9130G>A p.V3044I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs374628435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.2734C>A p.L912M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100096429; called by muse, mutect2, varscan2
- COPZ2 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV99133721; called by muse, mutect2, varscan2
- CORO1C | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs762661543, COSV99775984; called by muse, mutect2, varscan2
- CORO7 | c.2411G>A p.R804H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs774960939, COSV99068095; called by muse, mutect2, varscan2
- CPSF1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62942192; called by muse, mutect2, varscan2
- CPT1B | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777526020, COSV56415085; called by muse, mutect2, varscan2
- CPVL | c.794del p.K265Sfs*11 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs1562753933; called by mutect2, pindel, varscan2
- CPXM1 | c.1304A>G p.H435R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); catalogued as COSV101013745; called by muse, mutect2, varscan2
- CPXM2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs770522746, COSV53860400; called by muse, mutect2, varscan2
- CPXM2 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.044); catalogued as rs753988266, COSV53869562; called by muse, mutect2, varscan2
- CREBBP | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52117076; called by muse, mutect2, varscan2
- CROT | c.1171-2A>G p.X391_splice | Splice Site (SNP) | VAF 48/110 reads (44%) | catalogued as COSV100519542; called by muse, mutect2, varscan2
- CRTAC1 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs770267639, COSV53999139; called by muse, mutect2, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 29/54 reads (54%) | catalogued as rs769538822; called by mutect2, varscan2
- CSE1L | c.1126G>T p.G376* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99522054; called by muse, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 27/100 reads (27%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.6316G>A p.V2106M (on ENST00000520002; = p.V2105M on NM_033225.6) | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764452740, COSV59303920; called by muse, mutect2, varscan2
- CSMD2 | c.3973G>A p.V1325M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs142169949, COSV53884491; called by muse, mutect2, varscan2
- CSTF2 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs139392902, COSV65895569; called by muse, mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs1300471016; called by mutect2, pindel, varscan2
- CTCF | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1247514121, COSV99865539; called by muse, mutect2, varscan2
- CTNNA1 | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100242900; called by muse, mutect2, varscan2
- CTNNB1 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs753246841, COSV100846255; called by muse, varscan2
- CTTN | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774668913, COSV100097789; called by muse, mutect2, varscan2
- CUEDC1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.058); catalogued as rs139905264; called by muse, mutect2, varscan2
- CUL9 | c.4067G>A p.R1356H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1273543068, COSV99335483; called by muse, mutect2, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs782381199; called by mutect2, pindel, varscan2
- CXCL8 | c.*5del | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | catalogued as rs201169323; called by mutect2, pindel, varscan2
- CYFIP1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs747329807; called by muse, mutect2, varscan2
- CYP2C18 | c.794A>G p.D265G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99608586; called by muse, mutect2, varscan2
- CYP2D6 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs556882139; called by muse, mutect2
- DAB2 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs371133422, COSV57915080; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as rs751187768; called by mutect2, varscan2
- DAGLA | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as rs764510548, COSV99944047; called by muse, mutect2, varscan2
- DCAF1 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100244179; called by muse, mutect2, varscan2
- DCAF12 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778379; called by muse, mutect2, varscan2
- DCAF4 | c.271del p.L91* | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as COSV62320168; called by mutect2, pindel, varscan2
- DCHS1 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.438); catalogued as rs537298642, COSV100202122; called by muse, mutect2, varscan2
- DCHS1 | c.3311G>A p.R1104H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs757317023, COSV100202123; called by muse, mutect2, varscan2
- DCHS1 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as rs961424963, COSV100202125; called by muse, mutect2, varscan2
- DCHS1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs775548805, COSV100202126; called by muse, mutect2, varscan2
- DCK | c.415T>C p.S139P | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); catalogued as COSV99709218; called by muse, mutect2, varscan2
- DCST2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99791968; called by muse, mutect2, varscan2
- DCST2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.749); catalogued as rs754836792, COSV55050210; called by muse, mutect2, varscan2
- DDX1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV99246366; called by muse, varscan2
- DDX54 | c.598A>T p.I200F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100013928; called by muse, mutect2, varscan2
- DEFB132 | c.127del p.E43Rfs*51 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs776618282; called by mutect2, pindel, varscan2
- DENND10 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV100813946, COSV100813999; called by muse, mutect2, varscan2
- DENND6B | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs778185525, COSV100834096; called by muse, mutect2, varscan2
- DFFA | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148645727, COSV100986628; called by muse, mutect2, varscan2
- DHDH | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs140112768, COSV99668515; called by muse, mutect2, varscan2
- DHX33 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs368918561; called by muse, mutect2, varscan2
- DHX8 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs879524424, COSV52255463, COSV99292304; called by muse, mutect2, varscan2
- DIABLO | c.203C>T p.A68V (on ENST00000443649 / NM_001278303.1; = p.A141V on NM_019887.6) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99928239; called by muse, mutect2, varscan2
- DIDO1 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99826039; called by muse, mutect2, varscan2
- DIP2C | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as rs775934914, COSV99792008; called by muse, mutect2
- DIPK1B | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs772305344, COSV100765467; called by muse, mutect2, varscan2
- DLGAP3 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1412135893, COSV52396015; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH12 | c.574A>G p.S192G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100244579; called by mutect2, varscan2
- DNAH8 | c.5674G>T p.G1892C | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748575207, COSV100545688, COSV59486356; called by muse, mutect2, varscan2
- DNAJC14 | c.233del p.P78Qfs*178 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | catalogued as rs760590976; called by pindel, varscan2
- DOCK3 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as COSV99812572; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOP1B | c.6276G>A p.W2092* | Nonsense Mutation (SNP) | VAF 5/82 reads (6%) | catalogued as COSV67696119; called by muse, mutect2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as rs35482889; called by mutect2, varscan2
- DPH7 | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs3750384, COSV99480858; called by muse, mutect2, varscan2
- DPP3 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1027625928, COSV100291796; called by muse, mutect2, varscan2
- DPP3 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777823683, COSV100855618, COSV64757697; called by muse, mutect2, varscan2
- DRC1 | c.1851del p.W618Gfs*19 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs781097632, COSV55514089; called by mutect2, pindel, varscan2
- DSCAML1 | c.1624G>A p.V542M (on ENST00000321322; = p.V482M on NM_020693.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753446837, COSV58381771; called by muse, mutect2, varscan2
- DSG3 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99934235; called by muse, mutect2, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs1381179969; called by mutect2, pindel, varscan2
- DUSP15 | c.877T>C p.C293R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99639825; called by muse, mutect2, varscan2
- DUSP16 | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs866115319, COSV99963178; called by muse, mutect2, varscan2
- DYNC1H1 | c.11360C>T p.T3787M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs997706398, COSV100794984; called by muse, mutect2, varscan2
- E2F7 | c.177del p.K59Nfs*29 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as rs771114476; called by mutect2, varscan2
- EDRF1 | c.1943_1944insT p.E648Dfs*36 (on ENST00000356792 / NM_001202438.2; = p.E614Dfs*36 on NM_015608.2) | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | catalogued as COSV100523529; called by mutect2, pindel, varscan2
- EEF1A2 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV99419465; called by muse, mutect2, varscan2
- EEF2KMT | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 94/218 reads (43%) | catalogued as rs777822364, COSV99275785; called by muse, varscan2
- EFR3A | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs148528328; called by muse, mutect2, varscan2
- EGFR | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150549265, COSV51766389, COSV51769145; called by muse, mutect2, varscan2
- EHBP1L1 | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs774355413, COSV58573693; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs748937918; called by mutect2, varscan2
- ELFN2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68744751; called by muse, mutect2, varscan2
- ELP3 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs201078315; called by muse, mutect2, varscan2
- EMC10 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs200217945, COSV58542152; called by muse, mutect2, varscan2
- ENGASE | c.1638del p.T547Pfs*14 | Frame Shift Del (DEL) | VAF 15/56 reads (27%) | catalogued as rs759157900, COSV56136050; called by mutect2, pindel, varscan2
- ENTR1 | c.692C>T p.A231V (on ENST00000357365 / NM_001039707.2; = p.A208V on NM_006643.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs1471950980, COSV53743041; called by muse, mutect2
- EOMES | c.995dup p.K333Qfs*11 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | catalogued as rs1309565164; called by mutect2, pindel, varscan2
- EPHB2 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs201121087, COSV65865894; called by muse, mutect2, varscan2
- EPHB6 | c.1349del p.G450Dfs*10 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as COSV101235993; called by mutect2, pindel, varscan2
- EPN3 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV99277028; called by muse, varscan2
- EPS8 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs147224631; called by muse, mutect2, varscan2
- EPS8L2 | c.2137del p.E713Rfs*114 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1564981057; called by mutect2, pindel, varscan2
- ERBB2 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54072516, COSV99508121; called by muse, mutect2, varscan2
- ERCC6 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.198); catalogued as COSV63389371; called by muse, mutect2, varscan2
- ERG | c.1123G>A p.A375T (on ENST00000398919 / NM_001243428.1; = p.A351T on NM_004449.4) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55733296, COSV99901229; called by muse, mutect2, varscan2
- EXTL3 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217786288, COSV99594041; called by muse, mutect2, varscan2
- FAAP100 | c.2609A>G p.Y870C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1190457419, COSV58369106; called by muse, mutect2
- FAAP100 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1259932099, COSV100585405; called by muse, mutect2, varscan2
- FAM111B | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV100639299; called by muse, mutect2, varscan2
- FAM135B | c.4198G>A p.A1400T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV52744657, COSV99424459; called by muse, mutect2, varscan2
- FAM161A | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438804249, COSV100281315; called by muse, mutect2, varscan2
- FAM181A | c.827G>A p.C276Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99967898; called by muse, mutect2, varscan2
- FAM83F | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762810344, COSV100328942, COSV100328982; called by muse, mutect2, varscan2
- FAM83F | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.063); catalogued as rs567145342, COSV60999800; called by muse, mutect2
- FANCM | c.2002+2T>C p.X668_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99951110; called by muse, mutect2, varscan2
- FASLG | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs1041898198, COSV60679889; called by muse, mutect2, varscan2
- FASN | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs199956437, COSV100147870; called by muse, varscan2
- FASTKD3 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV99030145, COSV99241773; called by muse, varscan2
- FAT1 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV101499393; called by muse, mutect2, varscan2
- FBN2 | c.3709del p.R1237Afs*11 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as COSV99075148; called by mutect2, varscan2
- FBXL17 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62848957; called by muse, mutect2, varscan2
- FBXL4 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs779731686, COSV100014157; ClinVar: uncertain significance; called by muse, varscan2
- FBXO11 | c.1717G>T p.G573* (on ENST00000403359 / NM_001190274.2; = p.G489* on NM_025133.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100319553; called by muse, mutect2, varscan2
- FBXO34 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs369227884; called by muse, mutect2, varscan2
- FBXO46 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as rs781072997, COSV58348108; called by muse, mutect2, varscan2
- FBXO8 | c.433A>C p.T145P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV101183664; called by muse, mutect2, varscan2
- FBXW7 | c.751C>T p.L251F (on ENST00000281708 / NM_001349798.2; = p.L171F on NM_018315.5) | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.344); catalogued as COSV99657472; called by muse, mutect2, varscan2
- FCSK | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.703); catalogued as rs764197033, COSV99850930; called by muse, varscan2
- FGD6 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs762070123, COSV100676620; called by muse, mutect2, varscan2
- FHDC1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199815161; called by muse, mutect2, varscan2
- FHDC1 | c.1315del p.T439Pfs*2 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs1303890230; called by mutect2, pindel, varscan2
- FILIP1L | c.2191G>A p.A731T (on ENST00000354552 / NM_182909.3; = p.A491T on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.505); catalogued as COSV100496922; called by muse, mutect2, varscan2
- FKBP15 | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs765429463, COSV99406922; called by muse, mutect2, varscan2
- FLG | c.9613T>C p.S3205P | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV100911632; called by muse, mutect2, varscan2
- FLNB | c.5917G>A p.E1973K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as rs368965386, COSV55874339; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368192; called by muse, mutect2, varscan2
- FLT4 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs907068772, COSV56098172; called by muse, mutect2, varscan2
- FMNL1 | c.2974C>T p.R992C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs778995612, COSV58958892; called by muse, mutect2
- FNDC8 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763293774, COSV50101698; called by muse, mutect2, varscan2
- FOS | c.110_112del p.F37del | In Frame Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs1315892643; called by mutect2, pindel, varscan2
- FOXK1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100195292; called by muse, mutect2, varscan2
- FOXO3 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs1207616793, COSV59629397; called by muse, mutect2, varscan2
- FOXO4 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58575109; called by muse, mutect2, varscan2
- FOXP4 | c.1539C>T p.N513= (on ENST00000307972 / NM_001012426.1; = p.N500= on NM_138457.3) | Splice Region (SNP) | VAF 26/62 reads (42%) | catalogued as rs143123231; called by muse, mutect2, varscan2
- FOXRED2 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs771772376, COSV53401262; called by muse, mutect2, varscan2
- FRAS1 | c.4981A>G p.T1661A | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99352675; called by muse, mutect2, varscan2
- FREM1 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778272482, COSV101084703; called by muse, mutect2, varscan2
- FREM2 | c.1405G>C p.V469L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99749063; called by muse, mutect2, varscan2
- FRMD6 | c.1595G>A p.R532Q (on ENST00000344768 / NM_001267046.2; = p.R524Q on NM_152330.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.277); catalogued as rs748065189, COSV100655809, COSV100655919; called by muse, mutect2, varscan2
- FRY | c.7558G>A p.D2520N | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs755811736, COSV100969360; called by muse, mutect2, varscan2
- FRY | c.8764C>T p.R2922W | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs762239335, COSV66510835; called by muse, mutect2, varscan2
- FSCN3 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.194); catalogued as rs375801404, COSV50001234; called by muse, mutect2, varscan2
- FSCN3 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs569716722, COSV50000480, COSV50001239; called by muse, varscan2
- FSHB | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV99569437; called by muse, mutect2, varscan2
- FTCD | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1158463847, COSV99385127; called by muse, mutect2, varscan2
- FZD3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99528173; called by muse, mutect2, varscan2
- FZD6 | c.1213C>T p.R405W | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs186016315; called by muse, mutect2, varscan2
- GABRG3 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV100407617; called by muse, mutect2, varscan2
- GAK | c.1082-1G>T p.X361_splice | Splice Site (SNP) | VAF 39/97 reads (40%) | catalogued as COSV100033677; called by muse, mutect2, varscan2
- GBP7 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as rs531634408, COSV54010812; called by mutect2, varscan2
- GCNT3 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101251825; called by muse, mutect2, varscan2
- GGCX | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99289964; called by muse, mutect2, varscan2
- GIN1 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs976454950, COSV101204339; called by muse, mutect2, varscan2
- GJD2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768887810, COSV51750264, COSV99290643; called by muse, mutect2, varscan2
- GLI2 | c.1990G>A p.V664M (on ENST00000361492 / NM_001374353.1; = p.V681M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs551617843, COSV58045692; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | catalogued as rs749150409; called by mutect2, varscan2
- GNB5 | c.703G>A p.G235R (on ENST00000261837 / NM_016194.4; = p.G193R on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs13380232, COSV55898744; called by muse, mutect2, varscan2
- GOLGA1 | c.2032G>A p.A678T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.265); catalogued as COSV99414557; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.417); catalogued as rs1245348367; called by muse, varscan2
- GOLT1A | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs868308808, COSV100383485; called by muse, mutect2, varscan2
- GPAT3 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs746452375, COSV100023055; called by muse, mutect2, varscan2
- GPATCH1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as rs35914956; called by muse, mutect2, varscan2
- GPR132 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs778976347, COSV61677560, COSV61677833; called by muse, mutect2, varscan2
- GPR142 | c.563C>T p.T188I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1250991626, COSV100170843; called by muse, mutect2, varscan2
- GPR161 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs200315448, COSV99606710; called by muse, mutect2, varscan2
- GPR173 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as rs1556805893, COSV60238576; called by muse, mutect2, varscan2
- GPR179 | c.6020G>A p.G2007D (on ENST00000621958; = p.G2006D on NM_001004334.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753490497; called by muse, mutect2, varscan2
- GPR179 | c.2698del p.L900Cfs*70 (on ENST00000621958; = p.L899Cfs*70 on NM_001004334.4) | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs1216773012; called by mutect2, pindel, varscan2
- GPR50 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV54438480, COSV99506212; called by muse, mutect2, varscan2
- GPR52 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV99270833; called by muse, mutect2, varscan2
- GPR89A | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 69/195 reads (35%) | catalogued as rs782313035, COSV100572462; called by muse, mutect2, varscan2
- GRB7 | c.663+8del | Splice Region (DEL) | VAF 7/29 reads (24%) | catalogued as rs760897750; called by mutect2, pindel, varscan2
- GREB1 | c.2857C>T p.R953W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480723688, COSV52184921, COSV99303012; called by muse, mutect2, varscan2
- GRID2 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs754954663, COSV56170725; called by muse, mutect2, varscan2
- GRIK3 | c.2534A>G p.Y845C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs776408207, COSV100902105; called by muse, mutect2, varscan2
- GRIN2C | c.2429T>G p.L810R | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99501039; called by muse, mutect2, varscan2
- GRM2 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.545); catalogued as rs780930849, COSV99622882; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 30/58 reads (52%) | catalogued as rs754199513; called by mutect2, varscan2
- GSX1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57232345, COSV57233697; called by muse, mutect2, varscan2
- GTF3C3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1008295902, COSV99826748, COSV99826831; called by muse, mutect2, varscan2
- GUCY1A2 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as rs1407002811, COSV56479888, COSV99974968; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as COSV54945907; called by mutect2, varscan2
- GULP1 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs777577897, COSV63066743; called by muse, mutect2, varscan2
- GUSB | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs771629102, CM092098, COSV59222273; called by muse, mutect2, varscan2
- GYG2 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV100089030; called by muse, mutect2, varscan2
- H2AC20 | c.350T>G p.L117* | Nonsense Mutation (SNP) | VAF 40/98 reads (41%) | catalogued as COSV100479971; called by muse, mutect2, varscan2
- HASPIN | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748403043, COSV53994733; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs748396956; called by mutect2, varscan2
- HDAC7 | c.2521G>T p.G841C (on ENST00000427332; = p.G880C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99316218; called by muse, mutect2, varscan2
- HDAC8 | c.425A>G p.H142R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101002371; called by muse, mutect2, varscan2
- HDLBP | c.3451C>T p.R1151C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769840070, COSV100190802; called by muse, mutect2, varscan2
- HECA | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.617); catalogued as rs766148085, COSV62768641; called by muse, mutect2, varscan2
- HELZ2 | c.4456G>A p.V1486I (on ENST00000467148 / NM_001037335.2; = p.V917I on NM_033405.3) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.088); catalogued as rs61739518, COSV71296959; called by muse, mutect2, varscan2
- HIPK2 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100702280; called by muse, mutect2, varscan2
- HK3 | c.1599C>T p.S533= | Splice Region (SNP) | VAF 36/118 reads (31%) | catalogued as rs761405370, COSV99458626; called by muse, mutect2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs761272507; called by mutect2, varscan2
- HNRNPR | c.1600del p.A534Hfs*36 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs35459559; called by mutect2, pindel, varscan2
- HOXA6 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99762342; called by muse, mutect2, varscan2
- HOXC5 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758574102, COSV54536429; called by muse, mutect2, varscan2
- HRC | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs563550433, COSV99417998; called by muse, mutect2, varscan2
- HRH2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747648590, COSV51572764; called by muse, mutect2, varscan2
- HS3ST4 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.073); catalogued as COSV100501640; called by muse, mutect2, varscan2
- HSPA1B | c.1916A>G p.E639G | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV100987916; called by muse, mutect2, varscan2
- HSPG2 | c.9580G>A p.A3194T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV101013476; called by muse, mutect2, varscan2
- HSPG2 | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs557438464, COSV101020738; called by muse, mutect2, varscan2
- HTR1F | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs767724180, COSV60389492, COSV60390916; called by muse, mutect2, varscan2
- HTR6 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as rs887205866, COSV53876099; called by muse, mutect2, varscan2
- HYOU1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781950705, COSV101345616; called by muse, mutect2, varscan2
- IFT80 | c.698C>A p.T233N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100424802; called by muse, mutect2, varscan2
- IGDCC3 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs201555377; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGHV4-31 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.491); catalogued as rs767980132; called by muse, mutect2
- IGLV11-55 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs774625943, COSV101135371; called by muse, mutect2, varscan2
- IGSF10 | c.436C>G p.P146A | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs965535216, COSV99180535; called by muse, mutect2, varscan2
- IGSF21 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV99245146; called by muse, mutect2, varscan2
- IGSF3 | c.1589G>A p.R530H (on ENST00000369486 / NM_001007237.3; = p.R550H on NM_001542.4) | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs551475395, COSV59594210; called by muse, mutect2, varscan2
- IKZF3 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV104394122, COSV99499721; called by muse, mutect2, varscan2
- IL17RA | c.1405T>C p.C469R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.739); catalogued as COSV100083181; called by muse, mutect2, varscan2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 39/154 reads (25%) | catalogued as rs745545309; called by mutect2, pindel, varscan2
- ILVBL | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs762630633, COSV54623417; called by muse, mutect2, varscan2
- IMPDH1 | c.1060C>T p.R354W (on ENST00000470772 / NM_001142573.2; = p.R440W on NM_000883.4) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs773472205, COSV100118696; called by muse, mutect2, varscan2
- INO80 | c.3697C>T p.R1233C | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1364222217, COSV62736006; called by muse, mutect2, varscan2
- INTS2 | c.2779A>G p.K927E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99248218; called by muse, mutect2, varscan2
- INTS4 | c.2849A>C p.K950T | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100489990; called by muse, mutect2, varscan2
- INTS7 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100877224; called by muse, mutect2, varscan2
- IPMK | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs759900712, COSV64243468; called by muse, mutect2, varscan2
- IQCN | c.3536G>A p.G1179D | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100828299, COSV62748633; called by muse, mutect2, varscan2
- IQCN | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs146156071; called by muse, mutect2, varscan2
- IRF2BP1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1427888130, COSV100138901; called by muse, mutect2
- IRF4 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs751010198, COSV66704415; called by muse, mutect2, varscan2
- IRGQ | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100338170; called by muse, varscan2
- IRS1 | c.3480del p.K1161Rfs*20 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as COSV59339480; called by mutect2, pindel, varscan2
- IRX4 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51474582; called by muse, mutect2
- ITCH | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs776445457, COSV99392584; called by muse, varscan2
- ITFG1 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100278840; called by muse, mutect2, varscan2
- ITGA10 | c.242C>G p.A81G | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100994932; called by muse, mutect2, varscan2
- ITGA3 | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs140248487; called by muse, mutect2, varscan2
- ITGB3 | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs762965827, COSV71385247; called by muse, mutect2, varscan2
- ITPR3 | c.2800T>A p.S934T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.628); catalogued as COSV100967440; called by muse, mutect2, varscan2
- IZUMO1 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV99710830; called by muse, mutect2, varscan2
- JADE1 | c.1190T>A p.L397Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.36); catalogued as COSV99885879; called by muse, mutect2, varscan2
- JAK2 | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764302764, COSV101074146; called by muse, mutect2, varscan2
- JAKMIP1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557871910, COSV101290894; called by muse, mutect2, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1226801045; called by mutect2, varscan2
- KANSL2 | c.1013G>A p.C338Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100770970; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 23/53 reads (43%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNA6 | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99768683; called by muse, varscan2
- KCNC2 | c.800G>A p.G267D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV100129006; called by muse, mutect2, varscan2
- KCNH6 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV59007988; called by muse, mutect2, varscan2
- KCNJ12 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782311972, COSV100054434; called by muse, mutect2, varscan2
- KCNT2 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs200217178; called by muse, mutect2, varscan2
- KCTD15 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs774560706, COSV99393220; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KDR | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545112274, COSV55763636, COSV55771570; called by muse, mutect2, varscan2
- KIDINS220 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99875824; called by muse, mutect2, varscan2
- KIF12 | c.1478C>T p.A493V (on ENST00000640217; = p.A355V on NM_138424.1) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.104); catalogued as COSV100936164; called by muse, mutect2, varscan2
- KIF13A | c.5137G>A p.A1713T | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99436255; called by muse, mutect2, varscan2
- KIF1A | c.3905G>A p.R1302H (on ENST00000320389 / NM_001379639.1; = p.R1294H on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367749451, COSV100241187; called by muse, mutect2, varscan2
- KIF1B | c.4418G>A p.R1473Q (on ENST00000377086 / NM_001365952.1; = p.R1427Q on NM_015074.3) | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1384701975, COSV55817520, COSV99822855; called by muse, mutect2, varscan2
- KIF21A | c.4078_4080del p.L1360del (on ENST00000361418 / NM_001378440.1; = p.L1347del on NM_017641.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 25/61 reads (41%) | catalogued as rs773322171; called by pindel, varscan2
- KIF2B | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV52135781, COSV99082061; called by muse, mutect2, varscan2
- KIF3A | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1188757040, COSV66414035; called by muse, mutect2, varscan2
- KIF6 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1236802073, COSV99759080; called by muse, mutect2, varscan2
- KIF7 | c.1640del p.G547Afs*5 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as rs770571299, CX113624; called by mutect2, pindel, varscan2
- KLC4 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs368025562; called by muse, mutect2, varscan2
- KLHL2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as rs770856919, COSV99899999, COSV99900325; called by muse, mutect2, varscan2
- KLHL24 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs1256356011, COSV54427160; called by muse, mutect2, varscan2
- KLHL28 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs373899846, COSV100753073, COSV61889705; called by muse, mutect2, varscan2
- KLHL34 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs1286854210, COSV101069939; called by muse, mutect2, varscan2
- KLK7 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100304431; called by muse, mutect2, varscan2
- KLK8 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs747062903, COSV51593277; called by muse, mutect2, varscan2
- KMT2D | c.15545del p.G5182Afs*61 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV56464242; called by mutect2, pindel, varscan2
- KRBA1 | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs567865777, COSV55444251; called by muse, varscan2
- KRT71 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99922214; called by muse, mutect2, varscan2
- KRT75 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs865992888, COSV99359450; called by muse, mutect2, varscan2
- KRTDAP | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs141811528, COSV58865235; called by muse, mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 28/39 reads (72%) | catalogued as rs750491454; called by mutect2, varscan2
- LAIR2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.716); catalogued as COSV56621230; called by muse, mutect2, varscan2
- LAMA2 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123388, CM1311875, COSV101370516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LANCL2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760157909, COSV99634505; called by muse, mutect2, varscan2
- LCP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755322384, COSV59940540; called by muse, mutect2, varscan2
- LDHA | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs763532603, COSV57039258; called by muse, mutect2, varscan2
- LGALS3BP | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs757844460, COSV99431717; called by muse, varscan2
- LGALS9 | c.671C>T p.P224L (on ENST00000395473 / NM_009587.3; = p.P192L on NM_002308.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1436144317, COSV100119467; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs748571616; called by mutect2, varscan2
- LIMS2 | c.296G>A p.C99Y (on ENST00000355119 / NM_001161403.3; = p.C123Y on NM_017980.4) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99760624; called by muse, mutect2, varscan2
- LIN37 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99137455; called by muse, mutect2, varscan2
- LINS1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.051); catalogued as rs1357618303, COSV100130282; called by muse, mutect2, varscan2
- LIPK | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV101344983; called by muse, mutect2
- LIPN | c.1153C>T p.R385W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs185669405, COSV101356206, COSV101356225; called by muse, mutect2, varscan2
- LMNB1 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99745953; called by muse, mutect2, varscan2
- LMTK2 | c.3778G>A p.D1260N | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99806976; called by muse, mutect2, varscan2
- LPAR5 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as rs769378579, COSV61692216; called by muse, mutect2, varscan2
- LPCAT2 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs569284862, COSV100044881; called by muse, mutect2, varscan2
- LPIN3 | c.335del p.G112Vfs*69 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as rs756955559; called by mutect2, pindel, varscan2
- LRCH2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100406940; called by muse, mutect2, varscan2
- LRIT3 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV100016164; called by muse, mutect2, varscan2
- LRP12 | c.1907G>T p.R636I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99407814; called by muse, mutect2, varscan2
- LRP4 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as rs1023257694, COSV101066647; called by muse, mutect2, varscan2
- LRP5 | c.4000G>T p.A1334S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53722711; called by muse, mutect2
- LRP6 | c.848C>T p.T283I | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99743468; called by muse, mutect2, varscan2
- LRRC4B | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100975932; called by muse, mutect2, varscan2
- LRTM1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs773408157, COSV99836070; called by muse, varscan2
- LRTM1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs765585907, COSV55545184; called by muse, varscan2
- LSM14B | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755543275, COSV99444282; called by muse, mutect2, varscan2
- LTBP2 | c.5102G>A p.R1701H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs369856411; called by muse, mutect2, varscan2
- LTBP4 | c.3250C>T p.R1084W (on ENST00000308370 / NM_001042544.1; = p.R1047W on NM_003573.2) | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372889517; called by muse, mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs754757253, COSV52588935; called by mutect2, pindel, varscan2
- LYPLA2 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs775467458, COSV100994787; called by muse, mutect2, varscan2
- LYSMD3 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as rs1280667204, COSV60057236; called by muse, mutect2, varscan2
- LYST | c.7128T>A p.F2376L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV101089644, COSV67708413; called by muse, mutect2, varscan2
- LZTS1 | c.710G>A p.S237N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99743019; called by muse, mutect2, varscan2
- MACF1 | c.17382del p.W5795Gfs*8 (on ENST00000372915; = p.W3837Gfs*8 on NM_012090.5) | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs1431039831; called by mutect2, pindel, varscan2
- MAD1L1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); catalogued as rs377555260; called by muse, mutect2, varscan2
- MAEL | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63306182; called by muse, varscan2
- MAGEA8 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV99674628; called by muse, mutect2, varscan2
- MAGEE2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs769541561, COSV100973010, COSV100973116; called by muse, mutect2, varscan2
- MAGEL2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs764650142, COSV100045976; called by muse, mutect2, varscan2
- MAGI3 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1030023252, COSV100289337; called by muse, mutect2, varscan2
- MAGI3 | c.3386C>T p.P1129L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1299178971, COSV100289340; called by muse, mutect2, varscan2
- MAP1B | c.5263C>A p.P1755T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99702463; called by muse, mutect2, varscan2
- MAP2 | c.4943G>A p.R1648H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767308315, COSV52299926; called by muse, mutect2, varscan2
- MAP2K1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs1567009054, COSV61069333; ClinVar: uncertain significance; called by muse, varscan2
- MAP2K1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs910099707, COSV61070158, COSV61073627; called by muse, varscan2
- MAP3K21 | c.2143del p.Q715Rfs*236 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs1375324580, COSV64042370; called by mutect2, pindel, varscan2
- MAP3K4 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.394); catalogued as rs967543892, COSV100815425; called by muse, mutect2, varscan2
- MAPK8 | c.1138+2T>C p.X380_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV64408499; called by muse, mutect2, varscan2
- MAPKAP1 | c.1526C>T p.T509M (on ENST00000265960 / NM_001006617.3; = p.T473M on NM_024117.3) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1369730858, COSV99785082; called by muse, mutect2, varscan2
- MATN1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs368228632, COSV101056230; called by muse, mutect2, varscan2
- MBNL2 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs754344124, COSV100600431; called by muse, mutect2, varscan2
- MC1R | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400533954, COSV100205880; called by muse, mutect2, varscan2
- MC3R | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV54764169; called by muse, mutect2, varscan2
- MC5R | c.204C>A p.H68Q | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100228873; called by muse, mutect2, varscan2
- MCF2 | c.1628A>T p.D543V | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV58494827; called by muse, mutect2, varscan2
- MCM2 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781253937, COSV54034918; called by muse, mutect2, varscan2
- MCM3AP | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs190933622, COSV52439372; called by muse, mutect2, varscan2
- MCM3AP | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs139188881; called by muse, mutect2, varscan2
- MDH1 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251041; called by muse, mutect2, varscan2
- MDN1 | c.5602C>T p.Q1868* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV101020767; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 35/119 reads (29%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED12 | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV61335766; called by muse, mutect2, varscan2
- MED19 | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99762420; called by muse, mutect2, varscan2
- MEIOC | c.1690G>T p.G564* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100740249; called by muse, mutect2
- MEP1A | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1386229821, COSV57919986; called by muse, mutect2, varscan2
- METTL1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs776975890, COSV55745447; called by muse, mutect2, varscan2
- METTL6 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101085042; called by muse, mutect2, varscan2
- MFSD14B | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770993570, COSV100942694; called by muse, mutect2, varscan2
- MFSD9 | c.787A>T p.T263S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV99302128; called by muse, mutect2, varscan2
- MGAT5B | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100048134; called by muse, mutect2, varscan2
- MGRN1 | c.795+2T>C p.X265_splice | Splice Site (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99274300; called by muse, mutect2
- MICALL2 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV99875990; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIGA1 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100889780; called by muse, mutect2, varscan2
- MKI67 | c.6995C>T p.T2332M | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs182397079, COSV64073813; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as rs751465048; called by mutect2, varscan2
- MLLT10 | c.1298T>C p.F433S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.26); catalogued as rs1274551161, COSV100308222; called by muse, mutect2
- MLYCD | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs781550293, COSV99299315; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs755830405; called by mutect2, varscan2
- MPP5 | c.1537+1G>A p.X513_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as rs1444563382, COSV55528952; called by muse, mutect2
- MRAP | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs781703497, COSV57936395; called by muse, mutect2, varscan2
- MRE11 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as rs761458720, COSV60576711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH7 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs368938972, COSV100273586; called by muse, mutect2, varscan2
- MRPS5 | c.336del p.G113Efs*14 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1558684714; called by mutect2, pindel, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSGN1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV99808761; called by muse, mutect2, varscan2
- MSH5 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769834225, COSV65173531; called by muse, mutect2, varscan2
- MSN | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs746950857, COSV100814045; called by muse, mutect2, varscan2
- MTCL1 | c.4687A>G p.R1563G (on ENST00000306329 / NM_001378206.1; = p.R1244G on NM_015210.4) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100094739; called by muse, mutect2, varscan2
- MUC5B | c.7234G>A p.G2412S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761361228, COSV71591682; called by muse, mutect2, varscan2
- MUC6 | c.5677C>A p.P1893T | Missense Mutation (SNP) | VAF 64/616 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101424631, COSV70142775; called by muse, varscan2
- MUC7 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100512321; called by muse, mutect2, varscan2
- MVB12B | c.725A>G p.E242G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); catalogued as COSV100752920; called by muse, mutect2, varscan2
- MYBPC1 | c.1214C>T p.A405V (on ENST00000550270 / NM_206820.2; = p.A430V on NM_002465.4) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.938); catalogued as rs144105879; called by muse, mutect2, varscan2
- MYBPC2 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs368536456; called by muse, mutect2, varscan2
- MYH14 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs775868764, COSV51809717; called by muse, mutect2, varscan2
- MYH15 | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs764665272, COSV56304682; called by muse, mutect2, varscan2
- MYH4 | c.3479C>T p.A1160V | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as COSV55120783, COSV99701424; called by muse, mutect2, varscan2
- MYH8 | c.5143C>T p.R1715C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs376736272; called by muse, mutect2, varscan2
- MYLIP | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100785974; called by muse, mutect2, varscan2
- MYO10 | c.2248C>T p.R750W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs200913263, COSV57016569; called by muse, mutect2, varscan2
- MYO1G | c.2368G>A p.A790T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs755972612, COSV51856225; called by muse, mutect2, varscan2
- MYO1G | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV99348757; called by muse, mutect2, varscan2
- MYO1H | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs549049077, COSV60447087; called by muse, mutect2, varscan2
- MYO5B | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs753951906, COSV99545214; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 32/64 reads (50%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- NAP1L3 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100220420; called by muse, mutect2, varscan2
- NAT10 | c.2483A>G p.Y828C | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140137; called by muse, mutect2, varscan2
- NBEAL2 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99436153; called by muse, mutect2, varscan2
- NBEAL2 | c.3362C>T p.A1121V | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs868811988, COSV99436156; called by muse, mutect2
- NBEAL2 | c.5515C>T p.R1839C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750160418, CM116018, COSV99436159; called by muse, mutect2, varscan2
- NBN | c.2071-2A>G p.X691_splice | Splice Site (SNP) | VAF 27/86 reads (31%) | catalogued as COSV55375683; called by muse, mutect2, varscan2
- NCAPD3 | c.1028A>T p.D343V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV101596370; called by muse, mutect2, varscan2
- NCBP2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58317158; called by muse, mutect2, varscan2
- NCKAP5 | c.2554A>G p.S852G | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1176650237; called by muse, mutect2
- NCOA2 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs375519556; called by muse, mutect2, varscan2
- NCOA3 | c.3034G>A p.D1012N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs1410071299, COSV100507642; called by muse, mutect2, varscan2
- NDST1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747996016, COSV55790566, COSV99938845; called by muse, mutect2, varscan2
- NDUFA13 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.883); catalogued as rs759639695, COSV99388902; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs747914168; called by mutect2, varscan2
- NEB | c.18981_18982del p.R6327Sfs*9 | Frame Shift Del (DEL) | VAF 33/134 reads (25%) | catalogued as rs755863625; called by pindel, varscan2
- NEFL | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as rs1463847045, COSV99648004; called by muse, mutect2, varscan2
- NEK10 | c.2505+1G>A p.X835_splice | Splice Site (SNP) | VAF 40/93 reads (43%) | catalogued as rs768160759, COSV55355123; called by muse, mutect2, varscan2
- NEK8 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs1323633715, COSV52047126, COSV52047400; called by muse, mutect2, varscan2
- NELFA | c.1016C>T p.T339M (on ENST00000542778; = p.T328M on NM_005663.5) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs763739051, COSV56388586; called by muse, mutect2, varscan2
- NELFCD | c.1487T>C p.M496T (on ENST00000602795; = p.M478T on NM_198976.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV99413593; called by muse, mutect2, varscan2
- NEMF | c.2762C>A p.P921H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100027706; called by muse, mutect2, varscan2
- NES | c.1372C>T p.Q458* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100957882; called by muse, mutect2, varscan2
- NFE2L3 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99283764; called by muse, mutect2, varscan2
- NHSL2 | c.1676G>A p.R559Q (on ENST00000510661; = p.R925Q on NM_001013627.2) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs141959252, COSV101030140; called by muse, mutect2, varscan2
- NID1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs760345130, COSV99937616; called by muse, varscan2
- NIPBL | c.5018G>A p.R1673H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs770286768, COSV56942919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKX2-3 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100755092; called by muse, mutect2, varscan2
- NLGN1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | catalogued as rs1246921076, COSV64341360; called by muse, mutect2, varscan2
- NLGN3 | c.1454A>T p.E485V (on ENST00000358741 / NM_181303.2; = p.E465V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.046); catalogued as COSV100704815; called by muse, mutect2, varscan2
- NLRC5 | c.1637G>A p.R546H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs769612870, COSV99347475, COSV99348137; called by muse, mutect2, varscan2
- NLRC5 | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99347477; called by muse, mutect2, varscan2
- NLRP10 | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs775415713, COSV100149723; called by muse, mutect2, varscan2
- NLRP12 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs781341758, COSV60743424, COSV60751214; called by muse, mutect2, varscan2
- NLRP7 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.306); catalogued as COSV60181865; called by muse, mutect2, varscan2
- NOTCH1 | c.3513C>T p.C1171= | Splice Region (SNP) | VAF 12/47 reads (26%) | catalogued as rs758860870, COSV99488561; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOTCH2 | c.5104C>T p.R1702* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV56697310; called by muse, mutect2, varscan2
- NPC1 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745777805, CM032626, COSV99341410; ClinVar: uncertain significance; called by muse, varscan2
- NPLOC4 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV100480950; called by muse, mutect2, varscan2
- NPRL2 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1251989470, COSV99205161; called by muse, mutect2, varscan2
- NPTXR | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs200083748; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs774343392; called by mutect2, varscan2
- NRF1 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99781848; called by muse, mutect2, varscan2
- NRXN1 | c.3499C>T p.R1167* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs199546979, COSV58438923, COSV58455553; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- NRXN2 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760954823, COSV55463342; called by muse, mutect2, varscan2
- NSD1 | c.2810G>A p.R937Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs1023599621, COSV61782279; called by muse, mutect2, varscan2
- NTRK1 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100693435; called by muse, mutect2, varscan2
- NTSR1 | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as rs764341238, COSV100980652; called by muse, mutect2, varscan2
- NUDT10 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV62854609; called by muse, mutect2, varscan2
- NUDT14 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs754096722, COSV100242037; called by muse, mutect2, varscan2
- NUP160 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs900315105, COSV101021511; called by muse, mutect2, varscan2
- NUP214 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV63908789; called by muse, mutect2, varscan2
- NUP35 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs763888991, COSV54557562, COSV99717847; called by muse, mutect2, varscan2
- NUP50 | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100754355; called by muse, mutect2, varscan2
- NUTM2F | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as rs773225641, COSV99480163; called by muse, mutect2, varscan2
- OASL | c.313C>A p.L105M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99984548; called by muse, mutect2, varscan2
- OBP2B | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs553948862, COSV100922865; called by muse, mutect2, varscan2
- ODF3L2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757058500, COSV99199032; called by muse, mutect2, varscan2
- OGDH | c.240del p.R81Afs*19 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs777887578; called by mutect2, varscan2
- OGDH | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs764262872, COSV56051806, COSV99758977; called by muse, mutect2, varscan2
- OPCML | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100101987; called by muse, mutect2, varscan2
- OPRL1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs138440707; called by muse, mutect2, varscan2
- OR10A3 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs777277922, COSV62459854; called by muse, mutect2, varscan2
- OR1I1 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99264805; called by muse, mutect2, varscan2
- OR2H2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100589751; called by muse, mutect2
- OR51B4 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100971367; called by muse, mutect2, varscan2
- OR5AP2 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs369806983, COSV57258148; called by muse, mutect2, varscan2
- OR5AR1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs780660808, COSV57254597; called by muse, mutect2, varscan2
- OR8B2 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs529243218, COSV100899409; called by muse, mutect2, varscan2
- ORC1 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100856686; called by muse, mutect2, varscan2
- OXCT1 | c.1490A>G p.D497G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99542212; called by muse, mutect2, varscan2
- OXCT2 | c.959T>C p.I320T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100560284; called by muse, mutect2, varscan2
- P2RX1 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs765521009, COSV99844773; called by muse, mutect2, varscan2
- PABPC3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV99879576; called by muse, mutect2, varscan2
- PACS2 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as rs782050259, COSV57657568; called by muse, mutect2, varscan2
- PAK2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762853247, COSV100506156; called by mutect2, varscan2
- PAK2 | c.923A>C p.N308T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV59079067; called by muse, mutect2, varscan2
- PALB2 | c.2837C>T p.A946V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.211); catalogued as CM137607, COSV99848589; called by muse, mutect2, varscan2
- PAMR1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs529579135, COSV99552708; called by muse, mutect2, varscan2
- PANX2 | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99348371; called by muse, mutect2, varscan2
- PAPPA2 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100866823; called by muse, mutect2, varscan2
- PATL1 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.171); catalogued as rs762892994, COSV100274982; called by muse, mutect2, varscan2
- PATZ1 | c.533del p.P178Lfs*12 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as COSV53231424; called by mutect2, pindel, varscan2
- PAXIP1 | c.1538_1540dup p.Q513dup | In Frame Ins (INS) | VAF 26/80 reads (33%) | catalogued as rs1563372463; called by mutect2, varscan2
- PC | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs781568566, COSV100852247; called by muse, mutect2, varscan2
- PCDH10 | c.679dup p.Q227Pfs*19 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | catalogued as rs762465989; called by mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PCDH12 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766507231, COSV99189176; called by muse, mutect2, varscan2
- PCDH15 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.572); catalogued as rs1564545545, COSV100213918, COSV100214304; called by muse, mutect2, varscan2
- PCDHA1 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.386); catalogued as rs782343360, COSV100974374; called by muse, mutect2, varscan2
- PCDHA1 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.438); catalogued as COSV100974375; called by muse, mutect2, varscan2
- PCDHA13 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.438); catalogued as COSV56519981; called by muse, mutect2, varscan2
- PCDHB12 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99507355; called by muse, mutect2
- PCDHB13 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs781952167, COSV99507357; called by muse, mutect2, varscan2
- PCDHB14 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV99505989; called by muse, mutect2, varscan2
- PCDHB16 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs781890693, COSV99501902; called by muse, mutect2, varscan2
- PCDHB2 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.187); catalogued as COSV99165349; called by muse, mutect2, varscan2
- PCDHB2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV99165351; called by muse, mutect2, varscan2
- PCDHB7 | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 88/576 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.422); catalogued as rs782137017, COSV50757033; called by muse, mutect2, varscan2
- PCDHGA5 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as COSV53925693; called by muse, mutect2, varscan2
- PCDHGB1 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99539471; called by muse, mutect2, varscan2
- PCED1B | c.117G>T p.K39N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101423652, COSV71395620; called by muse, mutect2, varscan2
- PCF11 | c.2291G>A p.G764D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100018519; called by muse, mutect2, varscan2
- PCIF1 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184556937, COSV100533060; called by muse, mutect2, varscan2
- PCLO | c.9455C>T p.T3152M | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs188499676, COSV100433354; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.8174A>G p.E2725G | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64032497; called by muse, mutect2
- PCNX2 | c.5248C>T p.R1750W | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528200127, COSV50787897; called by muse, mutect2, varscan2
- PCOLCE | c.894del p.K299Sfs*41 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs755349242; called by mutect2, pindel, varscan2
- PDE5A | c.1240T>C p.Y414H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.261); catalogued as COSV99308779; called by muse, mutect2
- PDE8B | c.828T>A p.D276E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99366937; called by muse, varscan2
- PDE9A | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs770883595, COSV52325745, COSV52333182; called by muse, mutect2, varscan2
- PDIA4 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs372023035; called by muse, mutect2, varscan2
- PDZRN3 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs564100494, COSV99730009; called by muse, mutect2, varscan2
- PGAM2 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs375024229, COSV99803730; called by muse, mutect2, varscan2
- PGBD4 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs752721483, COSV99854882; called by muse, mutect2, varscan2
- PGC | c.1070G>A p.G357D | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs745956348, COSV100026241; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKA2 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as CM010992, COSV101177123; called by muse, mutect2, varscan2
- PHLPP1 | c.4666G>A p.V1556I | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774810238, COSV99408426; called by muse, mutect2, varscan2
- PHPT1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99915397, COSV99915694; called by muse, mutect2, varscan2
- PHRF1 | c.3233G>T p.R1078M (on ENST00000264555 / NM_001286581.2; = p.R1077M on NM_020901.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99200982; called by muse, mutect2, varscan2
1,012 further variants in this file (581 protein-altering or splice-affecting, 393 silent, 38 other) are not listed here.
